Gene-level copy-number profile of tumor specimen C3N-03666-01 from CPTAC case C3N-03666, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.6 years (23,228 days).
Specimen C3N-03666-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f39d84e2-9f09-4a5e-b07a-91072f036388.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03666-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/44e57456-13b8-4cbe-aa3b-f46de75d5633

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 295; copy number 2: 27,789; copy number 3: 24,028; copy number 4: 6,756; copy number 5: 10; copy number 11: 2; copy number 21: 3.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–22,455,740, 12 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr17:11,953,889–12,768,949, 12 genes (within-gene range 0–2): AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, LINC00670, AC068442.1, MYOCD, MYOCD-AS1.
- chr21:9,068,361–9,129,752, 3 genes: TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:49,531,946–49,620,646, 2 genes, copy number 5: RCBTB1, AL135901.1.
- chr17:51,312,609–52,535,701, 8 genes, copy number 5: LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982.
- chr22:18,605,355–18,611,919, 3 genes, copy number 21: AC023490.1, RN7SKP131, RIMBP3.
- chr22:18,623,339–18,638,405, 2 genes, copy number 11: SUSD2P2, CA15P2.

Autosomal genes at a single copy (total copy number 1): 271. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
